Gene-level copy-number profile of tumor specimen TCGA-04-1347-01A from TCGA case TCGA-04-1347, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 81.3 years (29,695 days).
Specimen TCGA-04-1347-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.41386f0c-6c92-4ae3-9b7a-fc2b98108e4f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1347-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/87df88b0-8cd0-4080-a298-a589faf2663a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,622; copy number 2: 6,817; copy number 3: 14,451; copy number 4: 10,789; copy number 5: 10,177; copy number 6: 6,878; copy number 7: 5,172; copy number 8: 2,548; copy number 9: 621; copy number 10: 312; copy number 11: 163; copy number 12: 146; copy number 13: 123.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1347-01A-01D-0428-01): tumor purity 0.94, ploidy 4.29, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 9,085 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:94,613,814–199,393,307, 1,983 genes, copy number 7–9 (broad region; genes not listed).
- chr1:214,532,195–219,613,145, 46 genes, copy number 8: KRT18P12, CENPF, ABHD17AP3, UBE2V1P13, GAPDHP24, AC099563.1, AC099563.2, KCNK2, VDAC1P10, AL450990.1, KCTD3, USH2A, SNORD116, AL358452.1, USH2A-AS2, USH2A-AS1, MRPS18BP1, ESRRG, GPATCH2, SPATA17, SPATA17-AS1, UBBP2, LINC00210, AL355526.1, LINC01653, AL355526.2, RNU1-141P, RRP15, AC096638.2, AC096638.1, TGFB2-AS1, TGFB2, TGFB2-OT1, LINC02869, U3, NXNP1, LINC01710, LYPLAL1-DT, LYPLAL1, RIMKLBP2, AL360093.1, AC096642.1, AC096642.2, LYPLAL1-AS1, AL356364.1, ZC3H11B.
- chr1:237,555,040–248,919,946, 271 genes, copy number 7–9 (broad region; genes not listed).
- chr2:38,814–35,725,142, 594 genes, copy number 7–8 (broad region; genes not listed).
- chr2:48,686,774–52,961,452, 36 genes, copy number 7 (within-gene range 6–7): LHCGR, ELOBP3, AC009975.1, CTBP2P5, FSHR, MIR548BA, AC009975.2, RNU6-439P, AC009971.1, RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3.
- chr3:90,030,284–198,222,513, 1,806 genes, copy number 7–12 (broad region; genes not listed).
- chr6:16,761,138–48,952,781, 1,075 genes, copy number 7 (broad region; genes not listed).
- chr6:54,846,771–61,681,049, 50 genes, copy number 7–13 (within-gene range 5–13): FAM83B, AL049555.1, HCRTR2, GFRAL, HMGCLL1, AL590290.1, BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1, AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1.
- chr6:83,852,312–85,777,755, 33 genes, copy number 11: AL139232.1, RIPPLY2, CYB5R4, AL034347.1, LINC02857, MRAP2, CEP162, LINC01611, SMARCE1P2, TBX18, TBX18-AS1, AL590143.1, AL035694.1, AL109941.1, AL139806.1, AL122016.1, AL135903.1, KRT18P64, LINC02535, DUTP5, TPT1P6, NT5E, AL589666.2, SNX14, AL589666.1, SYNCRIP, SNHG5, PKMP3, SNORD50B, AL355615.1, SMIM11P1, RNU4-72P, Y_RNA.
- chr6:91,390,313–92,180,156, 11 genes, copy number 8 (within-gene range 5–8): AL080284.1, MIR4643, CASC6, MTATP6P25, MTND4LP19, MTCO1P56, RN7SL415P, AL590635.1, AL590814.1, RPL5P19, U3.
- chr6:93,416,951–115,358,752, 275 genes, copy number 8–13 (within-gene range 5–13) (broad region; genes not listed).
- chr7:62,275,361–98,629,869, 666 genes, copy number 7 (broad region; genes not listed).
- chr7:132,648,794–148,420,998, 372 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr8:2,726,956–19,084,730, 386 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr8:31,275,542–37,095,390, 67 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr8:55,067,585–55,542,054, 4 genes, copy number 7 (within-gene range 5–7): AC084834.1, XKR4, AC022679.2, AC022679.1.
- chr8:60,629,662–63,478,745, 43 genes, copy number 7 (within-gene range 4–7): AC068389.1, AC068389.2, CHD7, AC113143.1, AC113143.2, IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1, AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P, AC011124.2.
- chr8:68,223,318–69,178,189, 11 genes, copy number 10: Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1.
- chr10:8,259,331–10,795,047, 25 genes, copy number 7: LINC00708, AL390835.1, AC025946.1, AC025946.2, KRT8P37, CHCHD3P1, RNA5SP299, AL355333.1, LINC02676, AC044784.1, LINC00709, AL138773.1, HSP90AB7P, LINC02663, LINC02670, ELOCP3, Y_RNA, CUX2P1, AL354916.1, AL583859.1, CELF2-DT, AL583859.2, AL583859.3, AL136452.1, SFTA1P.
- chr12:125,808,668–127,636,488, 50 genes, copy number 7: AC005252.2, AC005252.4, AC005252.3, AC005252.1, LINC00939, LINC02826, LINC02359, AC005858.2, AC005858.3, AC005858.1, AC005888.1, AC007368.1, LINC02825, LINC02347, FAM32EP, AC006065.1, NDUFA5P6, AC006065.4, AC006065.2, AC006065.3, AC006065.5, AC006065.6, LINC02824, LINC00943, LINC00944, AC078878.1, LINC02372, AC078878.2, HSPE1P20, LINC02405, AC079949.3, AC079949.1, AC079949.5, AC079949.2, AC079949.6, LINC02376, AC073913.1, RNU1-104P, LINC02375, AC073913.2, AC048347.1, AC068787.4, AC068787.1, AC068787.3, AC068787.2, AC068787.5, AC025252.1, Y_RNA, AC025252.2, LINC02411.
- chr14:25,124,467–26,208,424, 9 genes, copy number 11: LINC02286, HMGN2P6, OR7K1P, AL079352.1, LINC02306, AL359396.1, AL359396.2, AL132633.1, CYB5AP5.
- chr15:95,186,634–95,327,129, 1 gene, copy number 7 (within-gene range 5–7): LINC01197.
- chr15:95,280,753–98,087,384, 49 genes, copy number 7: AC104260.2, AC104260.3, LINC00924, AC027013.1, AC015574.1, RNU2-3P, AC012409.2, AC024337.1, AC024337.2, NR2F2-AS1, AC012409.5, AC012409.3, AC012409.1, AC012409.4, LINC02157, AC016251.1, NR2F2, MIR1469, AC103746.1, AC087477.2, TUBAP12, AC087477.5, AC087477.3, PGAM1P12, AC087477.1, AC087477.4, RN7SKP254, Metazoa_SRP, AC110588.1, FAM149B1P1, SPATA8-AS1, SPATA8, RN7SKP181, LINC02253, AC020704.1, LINC02254, RN7SL677P, RNA5SP401, AC026523.2, AC026523.1, AC026523.3, AC026523.4, LINC00923, AC024651.2, AC024651.3, ARRDC4, AC024651.1, LINC02251, U6.
- chr15:98,074,667–98,131,707, 4 genes, copy number 7: RNU6-1186P, LINC01582, AC022523.3, AC022523.2.
- chr17:51,630,313–54,771,277, 19 genes, copy number 7: CA10, AC002090.1, LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3, AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14.
- chr17:68,793,549–71,871,750, 37 genes, copy number 7: AC011591.1, ABCA8, ABCA9-AS1, ABCA9, ABCA6, SEC24AP1, MIR4524B, MIR4524A, ABCA10, PRO1804, AC005495.1, ABCA5, SNRPGP4, AC115085.1, MAP2K6, AC015920.1, AC002546.1, LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1, AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, AC007432.1, AC005144.1.
- chr19:27,681,072–27,984,984, 12 genes, copy number 7 (within-gene range 6–7): LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1.
- chr20:16,729,961–64,313,132, 1,150 genes, copy number 8–11 (within-gene range 6–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 246. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
